Surgical pathology report (de-identified scan), TCGA case TCGA-IR-A3LK, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-IR-A3LK-01A (Primary Tumor).

[page 1 of 2]
Specimens Submitted:

- 1: SP: Uterus, cervix, bilateral fallopian tubes and ovaries, radical hysterectomy and bilateral salpingo-oophorectomy
- 2: SP: Right external iliac lymph node, excisional biopsy
- 3: SP: Additional vagina, biopsy
- 4: SP: Right pelvic lymph nodes, excisional biopsy
- 5: SP: Left pelvic lymph nodes, excisional biopsy

DIAGNOSIS:

1. UTERUS, CERVIX, FALLOPIAN TUBES AND OVARIES; RADICAL HYSTERECTOMY AND BILATERAL SALPINGO-OOPHORECTOMY:
- MODERATELY TO POORLY DIFFERENTIATED INVASIVE SQUAMOUS CELL CARCINOMA OF THE CERVIX.
- THE TUMOR INVADES THE FULL THICKNESS OF THE 15 MM CERVICAL STROMA.
- THE TUMOR EXTENDS INTO THE LEFT PARAMETRIUM.
- THE POSTERIOR CERVICAL RESECTION MARGIN IS POSITIVE FOR CARCINOMA.
- ALL OTHER RESECTION MARGINS ARE NOT INVOLVED.
- BENIGN ENDOMETRIAL POLYP.
- UNREMARKABLE MYOMETRIUM.
- UNREMARKABLE BILATERAL FALLOPIAN TUBES AND LEFT OVARY.
- THREE BENIGN PARAMETRIAL LYMPH NODES (0/3).
2. LYMPH NODE, RIGHT EXTERNAL ILIAC; EXCISION:
- ONE BENIGN LYMPH NODE (0/1).
3. ADDITIONAL VAGINA; EXCISION:
- BENIGN SQUAMOUS MUCOSA.
4. LYMPH NODES, RIGHT PELVIC; EXCISION:
- SIX BENIGN LYMPH NODES (0/6).
5. LYMPH NODES, LEFT PELVIC; EXCISION:
- SEVEN BENIGN LYMPH NODES (0/7).

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF

** Continued on next page **

1CD-0-3

carcinoma, squamous cell 8070/3
Site: cervix, NOS C53.9 1w 12/20/11

[page 2 of 2]
THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED
THIS REPORT.

Source: NCI Genomic Data Commons file c49e6e65-d484-484d-8dff-72cf7fc32723 (TCGA-IR-A3LK.3AE8F93E-83B7-4501-B916-EC4EA9959F99.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).